Somatic mutation profile of tumor specimen C3N-00335-05 (aliquot CPT0018790006) from CPTAC case C3N-00335, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 57.7 years (21,084 days).
Specimen C3N-00335-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ec35e86-2fb4-477e-813c-1b840410603c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00335-31 (Blood Derived Normal), aliquot CPT0018910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cde2161-05b4-49f6-bdac-38c272cb32e8

The open-access MAF lists 1,466 somatic variants for this specimen: 996 protein-altering or splice-affecting, 288 silent, 182 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 700, Silent 288, Frame Shift Del 178, Intron 100, Frame Shift Ins 45, Nonsense Mutation 41, 3'UTR 29, RNA 19, 5'UTR 16, Splice Site 13, 5'Flank 12, Splice Region 9.

Variants (750 of 1,466; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 28/202 reads (14%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DMD | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 33/219 reads (15%) | catalogued as rs201366610, CM930192, COSV63767999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSP | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 44/416 reads (11%) | catalogued as rs768521444, COSV65792235; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel
- NAGLU | c.648dup p.S217Lfs*56 | Frame Shift Ins (INS) | VAF 54/314 reads (17%) | catalogued as rs760370189; ClinVar: pathogenic; called by mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 51/307 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 34/146 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SACS | c.6172del p.S2058Lfs*19 | Frame Shift Del (DEL) | VAF 35/153 reads (23%) | catalogued as rs1214399996, CD056852, CD1111485; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 46/246 reads (19%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TNFRSF11A | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121908657, CM083190; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA3 | c.2032G>A p.A678T | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs769584477; called by muse, mutect2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 42/194 reads (22%) | catalogued as rs777439793; called by mutect2, varscan2
- ACOT12 | c.1263-1G>T p.X421_splice | Splice Site (SNP) | VAF 15/117 reads (13%) | catalogued as COSV56894430; called by muse, mutect2, varscan2
- ACOX3 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs746824545; called by muse, mutect2, varscan2
- ACSM2B | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs200183083, COSV61656541; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS10 | c.2293del p.Q765Sfs*7 | Frame Shift Del (DEL) | VAF 46/225 reads (20%) | catalogued as rs782743337; called by mutect2, varscan2
- ADAMTS7 | c.1547G>A p.C516Y | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390606397; called by muse, mutect2, varscan2
- AFAP1L1 | c.748-2A>G p.X250_splice | Splice Site (SNP) | VAF 37/167 reads (22%) | catalogued as rs770551768; called by muse, mutect2, varscan2
- AFF2 | c.2792G>A p.S931N | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1029815702, COSV99664529; called by muse, mutect2, varscan2
- ALDH16A1 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs576632177, COSV53192917; called by muse, mutect2, varscan2
- ALDH1L1 | c.295del p.R99Gfs*62 | Frame Shift Del (DEL) | VAF 16/128 reads (13%) | catalogued as rs755422577, COSV99856805; called by mutect2, varscan2
- AMPD2 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 43/401 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs1344043194, COSV56647030; called by muse, mutect2, varscan2
- ANXA6 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753443419, COSV62907262; called by muse, mutect2, varscan2
- APC | c.6579del p.V2194Ffs*5 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | catalogued as rs775076289; called by mutect2, pindel
- APC2 | c.4789G>A p.V1597I | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs769619698; called by muse, mutect2, varscan2
- APEX2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1490536467, COSV100238531; called by muse, mutect2, varscan2
- APLP1 | c.1645C>T p.R549* (on ENST00000221891 / NM_001024807.3; = p.R548* on NM_005166.4) | Nonsense Mutation (SNP) | VAF 26/183 reads (14%) | catalogued as rs776958157, COSV55701572, COSV55702466; called by muse, mutect2, varscan2
- APOB | c.10331T>G p.L3444R | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51923922; called by muse, mutect2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 32/163 reads (20%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs746676748; called by mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 31/202 reads (15%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATOH8 | c.293del p.G98Afs*17 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs1169952443, COSV60401949; called by mutect2, pindel, varscan2
- B4GALNT4 | c.2654T>C p.L885P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57321762; called by muse, mutect2, varscan2
- B4GALT3 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100157767; called by muse, mutect2, varscan2
- BAG4 | c.606dup p.Q203Afs*24 | Frame Shift Ins (INS) | VAF 24/157 reads (15%) | catalogued as rs1347056564; called by mutect2, pindel, varscan2
- BCAR1 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs138576117; called by muse, mutect2, varscan2
- BIN2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1167510580; called by muse, mutect2
- C16orf96 | c.1375del p.E459Rfs*8 | Frame Shift Del (DEL) | VAF 32/150 reads (21%) | catalogued as rs1049972418, COSV71471644; called by pindel, varscan2
- C4orf54 | c.4640del p.P1547Qfs*70 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | catalogued as rs763082793; called by mutect2, pindel, varscan2
- C6orf136 | c.730C>T p.R244W (on ENST00000376473 / NM_001109938.3; = p.R110W on NM_145029.4) | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749442787, COSV53313633; called by muse, mutect2, varscan2
- CARMIL3 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs777634254, COSV57726004; called by muse, mutect2, varscan2
- CASKIN2 | c.1301T>C p.I434T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.313); catalogued as rs1386196443; called by muse, mutect2, varscan2
- CBLIF | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV57239020; called by muse, mutect2
- CCBE1 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs1252991567; called by muse, varscan2
- CCDC146 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1235472833; called by muse, mutect2
- CCDC157 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs941199116, COSV57841526; called by muse, mutect2
- CCDC88A | c.3603-3del | Splice Region (DEL) | VAF 14/66 reads (21%) | catalogued as rs768846308; called by mutect2, pindel, varscan2
- CD300C | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451715565; called by muse, mutect2
- CDK15 | c.221G>T p.R74L (on ENST00000652192 / NM_001366386.2; = p.R23L on NM_139158.2) | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.096); catalogued as COSV53638969; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5591A>G p.H1864R | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1220602164; called by muse, mutect2
- CDK9 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs370938433; called by muse, mutect2
- CEBPZ | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762777295, COSV50018623; called by muse, mutect2, varscan2
- CEL | c.1708G>A p.E570K (on ENST00000673714; = p.E567K on NM_001807.6) | Missense Mutation (SNP) | VAF 78/368 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs745724303; called by muse, varscan2
- CEP170B | c.3776C>T p.T1259M (on ENST00000453495; = p.T1188M on NM_015005.3) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs772190845; called by muse, mutect2, varscan2
- CFAP54 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs552575742; called by muse, mutect2, varscan2
- CFAP54 | c.5927G>A p.G1976D | Missense Mutation (SNP) | VAF 57/330 reads (17%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.622); catalogued as rs1217053202; called by muse, mutect2, varscan2
- CHADL | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as rs1413620431; called by muse, mutect2, varscan2
- CHD8 | c.7112del p.N2371Ifs*6 (on ENST00000646647 / NM_001170629.2; = p.N2092Ifs*6 on NM_020920.4) | Frame Shift Del (DEL) | VAF 26/138 reads (19%) | catalogued as rs751094013; called by mutect2, varscan2
- CHST1 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57323797; called by muse, mutect2, varscan2
- CLK2 | c.1253G>A p.R418H (on ENST00000368361 / NM_001294339.2; = p.R417H on NM_003993.4) | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs777248821, COSV56945480; called by muse, mutect2, varscan2
- CLUH | c.2015G>T p.S672I (on ENST00000435359; = p.S710I on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1331712396; called by muse, mutect2
- CNGA4 | c.164G>T p.R55I | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1174736220, COSV56410881, COSV99792479; called by muse, mutect2, varscan2
- CNMD | c.71del p.P24Rfs*6 | Frame Shift Del (DEL) | VAF 36/197 reads (18%) | catalogued as rs768157613; called by mutect2, pindel, varscan2
- CNTN1 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144047921; called by muse, mutect2
- COL15A1 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.898); catalogued as rs1271817403; called by muse, mutect2
- COL15A1 | c.3155C>G p.S1052C | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as rs149844223; called by muse, mutect2, varscan2
- COL7A1 | c.1634A>G p.Q545R | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as rs755721301; called by muse, mutect2, varscan2
- CRACD | c.1964del p.R655Pfs*22 | Frame Shift Del (DEL) | VAF 25/210 reads (12%) | catalogued as COSV51715473; called by mutect2, varscan2
- CROCC | c.5701G>A p.A1901T | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs768679535; called by muse, mutect2, varscan2
- CSK | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as rs1262834900, COSV99583637; called by muse, mutect2
- CSMD2 | c.6275C>T p.S2092L | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); catalogued as rs1008174420; called by muse, mutect2, varscan2
- CTR9 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100797551; called by muse, mutect2, varscan2
- CTTNBP2 | c.2119del p.L707Wfs*54 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | catalogued as COSV50390826; called by mutect2, varscan2
- DACH1 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as COSV57490241; called by mutect2, varscan2
- DCLK2 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.019); catalogued as rs777975269; called by muse, mutect2
- DCST1 | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs751299861, COSV55057035; called by muse, mutect2, varscan2
- DCTPP1 | c.101+1G>A p.X34_splice | Splice Site (SNP) | VAF 9/92 reads (10%) | catalogued as rs1488282946; called by muse, mutect2, varscan2
- DDX49 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1329168241; called by muse, mutect2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | catalogued as rs772416332; called by mutect2, varscan2
- DENND4C | c.966dup p.E323* | Frame Shift Ins (INS) | VAF 26/130 reads (20%) | catalogued as rs1428440687; called by mutect2, varscan2
- DISP2 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs576210510; called by muse, mutect2, varscan2
- DLGAP1 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752354203; called by muse, mutect2, varscan2
- DLX6 | c.804dup p.N269Qfs*59 | Frame Shift Ins (INS) | VAF 28/274 reads (10%) | catalogued as rs1469158094; called by mutect2, pindel
- DNAH17 | c.6214G>A p.G2072R | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs771686283, COSV67756913, COSV67758942; called by muse, mutect2, varscan2
- DNAI2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1228330378, COSV56756534; called by muse, mutect2, varscan2
- DNHD1 | c.7994G>A p.R2665H | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs753640133; called by muse, mutect2, varscan2
- DNMBP | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs139729649; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.5650del p.V1884Cfs*110 | Frame Shift Del (DEL) | VAF 12/123 reads (10%) | catalogued as COSV70237544; called by mutect2, pindel
- DOCK6 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.279); catalogued as rs1482931548, COSV52949517; called by muse, mutect2
- DRD4 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1341566170; called by muse, mutect2, varscan2
- DUSP21 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV59133908; called by muse, mutect2, varscan2
- DUSP26 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs745976867, COSV56361442; called by muse, mutect2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 16/120 reads (13%) | catalogued as rs772082432; called by mutect2, varscan2
- EFCAB13 | c.2321G>A p.G774D | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.924); catalogued as COSV58949391; called by muse, mutect2, varscan2
- EOMES | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs534406435; called by muse, mutect2
- EPHA10 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs377655424; called by muse, mutect2, varscan2
- ERBB4 | c.3685A>G p.M1229V | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs774554133; called by muse, mutect2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 85/224 reads (38%) | catalogued as rs775950025; called by mutect2, varscan2
- F13A1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs138865075; called by muse, mutect2, varscan2
- FAM111A | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV64655570; called by muse, mutect2
- FAM193B | c.219del p.A74Pfs*49 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as rs765995572, COSV61557636; called by mutect2, pindel, varscan2
- FARP2 | c.510G>A p.S170= | Splice Region (SNP) | VAF 13/93 reads (14%) | catalogued as rs144589035; called by muse, mutect2, varscan2
- FASN | c.7173G>T p.K2391N | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.153); catalogued as rs534913727; called by muse, mutect2, varscan2
- FBXW5 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs372873658; called by muse, mutect2
- FIZ1 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 17/266 reads (6%) | catalogued as rs769485749; called by muse, mutect2
- FKRP | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs1325525979; called by muse, mutect2
- FLG | c.2068A>G p.S690G | Missense Mutation (SNP) | VAF 76/501 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs775610475; called by muse, mutect2, varscan2
- FLT4 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 71/380 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs372947534; called by muse, mutect2, varscan2
- FNDC7 | c.1900del p.V634* | Frame Shift Del (DEL) | VAF 23/113 reads (20%) | catalogued as COSV54754096; called by mutect2, pindel, varscan2
- FNIP1 | c.2773del p.I925Lfs*3 | Frame Shift Del (DEL) | VAF 45/219 reads (21%) | catalogued as COSV100330154; called by mutect2, pindel, varscan2
- FOXK1 | c.731del p.P244Rfs*29 | Frame Shift Del (DEL) | VAF 9/62 reads (15%) | catalogued as COSV61065108; called by mutect2, pindel, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FREM2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as COSV54832830; called by muse, mutect2, varscan2
- FRMPD3 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1474729948, COSV99346518; called by muse, mutect2
- FZD10 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57472354; called by muse, mutect2, varscan2
- FZR1 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs1241668087; called by muse, varscan2
- GAL3ST2 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs1380310801; called by muse, mutect2
- GATA4 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 70/496 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1305097777; called by muse, mutect2, varscan2
- GBP2 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 29/356 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as rs760121831, COSV65069182; called by muse, mutect2
- GBP4 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.26); catalogued as COSV63254568; called by muse, mutect2, varscan2
- GCM2 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 27/231 reads (12%) | catalogued as rs748030466, COSV65275310; called by muse, mutect2, varscan2
- GFOD1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64955195; called by muse, mutect2, varscan2
- GGA1 | c.1624G>C p.V542L | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100289786; called by muse, mutect2
- GIGYF2 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101003915; called by muse, mutect2, varscan2
- GIPC1 | c.149del p.P50Lfs*48 | Frame Shift Del (DEL) | VAF 27/152 reads (18%) | catalogued as rs771881138; called by mutect2, varscan2
- GLDC | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 71/394 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV100393947; called by muse, mutect2, varscan2
- GLI2 | c.1693C>T p.R565W (on ENST00000361492 / NM_001374353.1; = p.R582W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/445 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158908764; called by muse, mutect2, varscan2
- GLIPR1L2 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867208949, COSV57553085; called by muse, mutect2
- GMIP | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52291885; called by muse, mutect2, varscan2
- GNAS | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1200405971, COSV58345558; called by muse, mutect2, varscan2
- GP2 | c.1568C>T p.A523V (on ENST00000381362 / NM_001007240.3; = p.A520V on NM_001502.4) | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs201879579; called by muse, mutect2, varscan2
- GPR101 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV53240683; called by muse, mutect2
- GPR132 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs769671782, COSV61678317; called by muse, mutect2, varscan2
- GPR146 | c.521G>C p.R174P | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV52465431, COSV52466314; called by muse, mutect2, varscan2
- GPR158 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs1422798836; called by muse, mutect2
- GPR17 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs372161035; called by muse, mutect2, varscan2
- GPR68 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752894280; called by muse, mutect2, varscan2
- GRIN3A | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as rs1254592748, COSV62454102; called by muse, mutect2
- GUCY2D | c.2984G>A p.R995Q | Missense Mutation (SNP) | VAF 83/347 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777075412, CM155806; called by muse, mutect2, varscan2
- HEMK1 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs1303645255; called by muse, mutect2
- HNF4A | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 94/395 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.18); catalogued as COSV57383849; called by muse, mutect2, varscan2
- HOXA4 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1562723170; called by muse, mutect2, varscan2
- HOXA6 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376435844; called by muse, mutect2, varscan2
- HSPA12B | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV54765558; called by muse, mutect2
- HSPG2 | c.11923C>G p.P3975A | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60827370; called by muse, mutect2
- ICAM5 | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.861); catalogued as COSV55746440; called by muse, mutect2
- IGFALS | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as CM0910686; called by muse, mutect2, varscan2
- IL17A | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780218416, COSV60684979, COSV60685375; called by muse, mutect2, varscan2
- INAVA | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV66256953; called by muse, mutect2, varscan2
- IPO4 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs747824181; called by muse, mutect2, varscan2
- IQCE | c.1616del p.K539Rfs*25 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | catalogued as rs759821884; called by mutect2, varscan2
- ITGA4 | c.902del p.K301Sfs*50 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | catalogued as COSV99275859; called by mutect2, pindel, varscan2
- ITPRID1 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1026235574; called by muse, varscan2
- JAK3 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs200740037; called by muse, mutect2, varscan2
- JPH2 | c.62del p.G21Efs*54 | Frame Shift Del (DEL) | VAF 16/151 reads (11%) | catalogued as rs1206579645; called by mutect2, pindel
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 34/188 reads (18%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNU1 | c.2732C>T p.A911V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101299330; called by muse, mutect2, varscan2
- KCNV2 | c.929T>C p.M310T | Missense Mutation (SNP) | VAF 144/808 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs747021960; called by muse, mutect2, varscan2
- KHDRBS3 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs751628299, COSV100878809, COSV100879099; called by muse, mutect2, varscan2
- KHK | c.653+8G>A | Splice Region (SNP) | VAF 33/192 reads (17%) | catalogued as rs369037689; called by muse, mutect2, varscan2
- KIAA0100 | c.5962C>T p.R1988C | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760118789; called by muse, mutect2, varscan2
- KIAA1671 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.623); catalogued as rs1023882975; called by muse, mutect2
- KIF13B | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV72961991; called by muse, mutect2
- KIF4B | c.2375C>A p.P792H | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV70530346; called by muse, mutect2, varscan2
- KIR3DL1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 75/535 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs1452407180, COSV100428623; called by muse, varscan2
- KLHDC4 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs374406978; called by mutect2, varscan2
- KLHL29 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 73/458 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.08); catalogued as rs563441134; called by muse, mutect2, varscan2
- KLHL40 | c.299G>C p.S100T | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV55133289; called by muse, mutect2
- KLHL40 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1308853901; called by muse, mutect2, varscan2
- KLK15 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1568483222, COSV56825742, COSV56827015; called by muse, mutect2, varscan2
- KPNA5 | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62651408, COSV62653082; called by muse, mutect2, varscan2
- KRTAP4-6 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 40/776 reads (5%) | SIFT tolerated (0.07); catalogued as COSV61981201; called by muse, mutect2
- LAMC3 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 70/342 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs753037720; called by muse, mutect2, varscan2
- LDHAL6B | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1384433013; called by muse, mutect2
- LGALS1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1482317143; called by muse, mutect2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 32/118 reads (27%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LILRA4 | c.1302G>T p.K434N | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.12); catalogued as COSV52494358; called by muse, mutect2
- LIMK2 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs890335349, COSV59182850; called by muse, mutect2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 25/110 reads (23%) | catalogued as rs765287063; called by mutect2, varscan2
- LONP1 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.073); catalogued as COSV100638831; called by muse, mutect2, varscan2
- LTK | c.2552del p.G851Afs*? | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | catalogued as COSV99540687; called by mutect2, pindel, varscan2
- LYPD6 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs375770091; called by muse, mutect2, varscan2
- LZTS2 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs761447747, COSV64652249; called by muse, mutect2
- MAGEE2 | c.1301T>C p.V434A | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.983); catalogued as COSV64897858; called by muse, mutect2
- MAP1A | c.7435C>T p.R2479W | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs766441031, COSV55811917; called by muse, mutect2, varscan2
- MAP3K12 | c.1874C>G p.A625G | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.037); catalogued as rs201286832; called by mutect2, varscan2
- MAPK10 | c.73C>T p.R25C (on ENST00000359221 / NM_001351625.2; = p.R63C on NM_002753.5) | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773390425, COSV60384294; called by muse, mutect2, varscan2
- MAST4 | c.5290C>T p.R1764W (on ENST00000403625 / NM_001164664.2; = p.R1575W on NM_015183.3) | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1489748859; called by muse, mutect2
- MAT1A | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 94/607 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs773267230, CM960954, COSV64744759; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as rs746267361; called by mutect2, varscan2
- MBOAT4 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1404642148; called by muse, mutect2
- MED15 | c.1307C>T p.P436L (on ENST00000263205 / NM_001003891.3; = p.P396L on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs531964697; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MEIOC | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs777721724; called by muse, mutect2, varscan2
- MERTK | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.023); catalogued as COSV54935919; called by muse, mutect2, varscan2
- MEX3B | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1243022967, COSV100314051; called by muse, mutect2, varscan2
- MGAT4C | c.336del p.G113Efs*20 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as rs1347429614; called by mutect2, pindel, varscan2
- MLLT10 | c.1231del p.V411* | Frame Shift Del (DEL) | VAF 12/113 reads (11%) | catalogued as rs747811015; called by mutect2, pindel
- MMP10 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1460636886; called by muse, mutect2, varscan2
- MMRN1 | c.2646del p.G883Afs*3 | Frame Shift Del (DEL) | VAF 11/122 reads (9%) | catalogued as rs750319971; called by mutect2, pindel
- MNX1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 53/524 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV104386246; called by muse, mutect2, varscan2
- MOCOS | c.1516G>C p.G506R | Missense Mutation (SNP) | VAF 29/231 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54342119; called by muse, mutect2, varscan2
- MOV10 | c.2632A>G p.I878V | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs773433668; called by muse, mutect2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRS2 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs778049258, COSV99219226; called by muse, mutect2, varscan2
- MTM1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs374075654, COSV60335191; called by muse, mutect2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs537060918; called by mutect2, varscan2
- MYBPH | c.14del p.N5Tfs*73 | Frame Shift Del (DEL) | VAF 24/189 reads (13%) | catalogued as rs752878638; called by mutect2, pindel
- MYCBP2 | c.13186G>T p.E4396* (on ENST00000357337; = p.E4434* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 11/128 reads (9%) | catalogued as COSV100629000; called by muse, mutect2
- MYO10 | c.3493C>T p.R1165W | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as rs779886227, COSV99946609; called by muse, mutect2, varscan2
- MYO1A | c.1682dup p.T562Dfs*32 | Frame Shift Ins (INS) | VAF 67/392 reads (17%) | catalogued as rs746990682; called by mutect2, pindel, varscan2
- MYOG | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1451908431; called by muse, mutect2, varscan2
- NCK2 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.927); catalogued as rs756566928; called by muse, mutect2, varscan2
- NCOA7 | c.2187G>T p.K729N | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773178871; called by muse, mutect2, varscan2
- NEO1 | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0.031); catalogued as COSV56075945; called by muse, mutect2, varscan2
- NGF | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV65686874; called by muse, mutect2, varscan2
- NHLH1 | c.128del p.G43Afs*19 | Frame Shift Del (DEL) | VAF 42/207 reads (20%) | catalogued as rs1228117128, COSV57484266; called by mutect2, pindel, varscan2
- NLGN4X | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 77/435 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52022494, COSV52025091; called by muse, mutect2, varscan2
- NLRP1 | c.3820C>T p.R1274* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs866926418, COSV52567113; called by muse, mutect2
- NMBR | c.768del p.K256Nfs*45 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as rs1470345555; called by mutect2, pindel, varscan2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOS1 | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1330112610, COSV57610393; called by muse, mutect2, varscan2
- NOTCH1 | c.5785G>A p.E1929K | Missense Mutation (SNP) | VAF 84/418 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV53078596, COSV53084921; called by muse, mutect2, varscan2
- NTMT1 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.862); catalogued as rs756650474; called by muse, mutect2, varscan2
- NUMA1 | c.3934C>T p.R1312W | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs769545751, COSV100706332; called by muse, mutect2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 39/168 reads (23%) | catalogued as rs758695627; called by mutect2, varscan2
- NWD1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as rs560096144; called by muse, mutect2, varscan2
- OBSL1 | c.5444del p.P1815Lfs*16 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs748594277, COSV54705399; called by mutect2, varscan2
- OLFM2 | c.1300_1302del p.N434del | In Frame Del (DEL) | VAF 48/209 reads (23%) | catalogued as rs772988752; called by pindel, varscan2
- OR51V1 | c.507del p.F169Lfs*22 | Frame Shift Del (DEL) | VAF 40/213 reads (19%) | catalogued as COSV58314978; called by mutect2, pindel, varscan2
- OTUB2 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs779026394; called by muse, mutect2, varscan2
- PABPC5 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1446595654, COSV57038971, COSV57039392; called by muse, mutect2, varscan2
- PAN2 | c.2119C>T p.R707* (on ENST00000425394 / NM_001127460.3; = p.R703* on NM_014871.5) | Nonsense Mutation (SNP) | VAF 13/167 reads (8%) | catalogued as rs759172607; called by muse, mutect2
- PCCA | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1442819667, COSV66195665; called by muse, mutect2
- PCDH15 | c.2087A>T p.D696V | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1168427755; called by muse, mutect2
- PCDHA1 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 22/704 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.089); catalogued as COSV65372535; called by muse, mutect2
- PCSK6 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs867788887; called by muse, mutect2, varscan2
- PDE4DIP | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); catalogued as rs374875259; called by muse, mutect2
- PDGFD | c.640dup p.I214Nfs*5 | Frame Shift Ins (INS) | VAF 34/197 reads (17%) | catalogued as rs1333395128; called by mutect2, varscan2
- PDGFRL | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs111243093; called by muse, mutect2, varscan2
- PDZD2 | c.7156G>T p.G2386C | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV99227227; called by muse, mutect2, varscan2
- PENK | c.635del p.G212Afs*3 | Frame Shift Del (DEL) | VAF 17/116 reads (15%) | catalogued as rs1386766507; called by mutect2, pindel, varscan2
- PGPEP1L | c.349A>T p.I117F | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.379); catalogued as rs556119714; called by muse, mutect2, varscan2
- PKN3 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs752533632, COSV52577171; called by muse, mutect2, varscan2
- PKNOX1 | c.1036del p.W346Gfs*31 | Frame Shift Del (DEL) | VAF 78/457 reads (17%) | catalogued as COSV52335122; called by mutect2, pindel, varscan2
- PLAAT5 | c.169del p.E58Nfs*2 | Frame Shift Del (DEL) | VAF 38/168 reads (23%) | catalogued as rs752453390; called by mutect2, varscan2
- PLCG2 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1024473204, COSV63878606; ClinVar: uncertain significance; called by muse, mutect2
- PLOD1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760372600; called by muse, mutect2, varscan2
- PMFBP1 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773219253; called by muse, mutect2, varscan2
- PNMA8A | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV58136333; called by muse, mutect2, varscan2
- POLM | c.290dup p.A98Sfs*73 | Frame Shift Ins (INS) | VAF 18/96 reads (19%) | catalogued as rs745933237; called by mutect2, varscan2
- POLR1C | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 75/453 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.451); catalogued as rs750727358; called by muse, mutect2, varscan2
- POLR2A | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.33); catalogued as rs1567703555; called by muse, mutect2
- POP1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as rs1466730210; called by muse, mutect2
- PPP1R36 | c.924del p.A309Lfs*31 | Frame Shift Del (DEL) | VAF 13/102 reads (13%) | catalogued as COSV53901642; called by mutect2, pindel, varscan2
- PPP1R9A | c.1250del p.T417Kfs*81 | Frame Shift Del (DEL) | VAF 22/242 reads (9%) | catalogued as COSV99199043; called by mutect2, pindel
- PPP4C | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54221832; called by muse, mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 22/128 reads (17%) | catalogued as rs768056539; called by mutect2, varscan2
- PRKCB | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57804046; called by muse, mutect2
- PRRC2A | c.3238C>T p.R1080* | Nonsense Mutation (SNP) | VAF 16/146 reads (11%) | catalogued as rs868312958; called by muse, mutect2
- PSMB8 | c.787G>A p.D263N (on ENST00000374882 / NM_148919.4; = p.D259N on NM_004159.5) | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as COSV62755595; called by muse, mutect2, varscan2
- PSMD6 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1281369909, COSV55759088; called by muse, mutect2, varscan2
- PTBP1 | c.931del p.L311Wfs*57 (on ENST00000349038 / NM_031991.4; = p.L337Wfs*57 on NM_002819.5) | Frame Shift Del (DEL) | VAF 17/140 reads (12%) | catalogued as rs1421431048; called by mutect2, pindel, varscan2
- PYCARD | c.7C>G p.R3G | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1386704738; called by muse, mutect2
- PYROXD2 | c.1552G>T p.G518W | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65331736; called by muse, mutect2, varscan2
- R3HDM2 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1052663918, COSV61285475; called by muse, mutect2, varscan2
- RAB11B | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.113); catalogued as rs866295821; called by muse, mutect2
- RALGDS | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV100924430; called by muse, mutect2
- RASIP1 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs1484684850; called by muse, mutect2, varscan2
- RBM26 | c.2982T>A p.D994E (on ENST00000438737 / NM_001366735.2; = p.D967E on NM_022118.5) | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as COSV57395626; called by muse, mutect2
- RCBTB1 | c.85A>G p.T29A | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1418552292; called by muse, mutect2, varscan2
- RETSAT | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV99806321; called by muse, mutect2, varscan2
- REV1 | c.3680T>C p.M1227T | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.343); catalogued as rs753772487; called by muse, mutect2, varscan2
- RGR | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 39/598 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as rs139595177; called by muse, mutect2
- RHPN1 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765954419; called by muse, mutect2, varscan2
- RIC8B | c.980del p.L327* | Frame Shift Del (DEL) | VAF 29/161 reads (18%) | catalogued as COSV62697147; called by mutect2, pindel, varscan2
- RIMBP2 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745374088, COSV55474609; called by muse, mutect2, varscan2
- RIMS1 | c.2873G>A p.R958H | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373238402, COSV99327156; called by muse, mutect2, varscan2
- RIMS2 | c.3725T>C p.I1242T | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as rs780372267; called by muse, mutect2, varscan2
- RNASEL | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145415894, COSV62376558; called by muse, mutect2, varscan2
- RNASET2 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 74/339 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs62436422; called by muse, mutect2, varscan2
- RNF31 | c.1405dup p.L469Pfs*9 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs1345318912; called by mutect2, pindel, varscan2
- ROS1 | c.2569C>A p.L857M | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752798332, COSV100877822; called by muse, mutect2, varscan2
- ROS1 | c.1469T>C p.I490T | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100876905; called by muse, mutect2, varscan2
- RP1L1 | c.851del p.P284Rfs*26 | Frame Shift Del (DEL) | VAF 104/542 reads (19%) | catalogued as rs757272743; called by mutect2, pindel, varscan2
- RRP1B | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs763993695; called by mutect2, varscan2
- SALL2 | c.1586del p.P529Qfs*22 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs755171367; called by mutect2, pindel, varscan2
- SAP30BP | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758845704, COSV53130608; called by muse, mutect2
- SCAF11 | c.312dup p.Q105Tfs*11 | Frame Shift Ins (INS) | VAF 13/113 reads (12%) | catalogued as rs758155797; called by mutect2, varscan2
- SCN11A | c.1473G>A p.K491= | Splice Region (SNP) | VAF 10/54 reads (19%) | catalogued as rs1462272477; called by muse, varscan2
- SCN1A | c.3601G>T p.G1201* (on ENST00000303395 / NM_001202435.3; = p.G1190* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/250 reads (22%) | catalogued as CM113314; called by muse, mutect2, varscan2
- SDHA | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as rs979815942, COSV99371155; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERAC1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as COSV65598250; called by muse, mutect2
- SERPINB11 | c.618+1G>A p.X206_splice | Splice Site (SNP) | VAF 10/140 reads (7%) | catalogued as COSV66956385; called by muse, mutect2
- SH3PXD2A | c.1715G>T p.S572I (on ENST00000369774 / NM_001365079.1; = p.S544I on NM_014631.2) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); catalogued as COSV60117060; called by muse, mutect2, varscan2
- SH3PXD2A | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1176333434, COSV100583979, COSV63509838; called by muse, mutect2
- SH3RF3 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs984663872; called by muse, mutect2, varscan2
- SH3TC2 | c.2275C>A p.L759M | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100102037, COSV60460484; called by muse, mutect2
- SHROOM2 | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.097); catalogued as COSV101098999; called by muse, varscan2
- SIPA1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as rs1473161702, COSV63141550; called by muse, mutect2, varscan2
- SIPA1L1 | c.172del p.R58Efs*8 | Frame Shift Del (DEL) | VAF 19/148 reads (13%) | catalogued as rs1567251966; called by mutect2, pindel, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC13A2 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375817516; called by muse, mutect2, varscan2
- SLC25A20 | c.376G>T p.G126* | Nonsense Mutation (SNP) | VAF 72/423 reads (17%) | catalogued as COSV100033659, COSV59803460; called by muse, mutect2, varscan2
- SLC26A1 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as rs765881732; called by muse, mutect2
- SLC39A8 | c.636dup p.E213* | Frame Shift Ins (INS) | VAF 22/120 reads (18%) | catalogued as rs59385228; called by pindel, varscan2
- SLC45A1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1467070473, COSV57097309; called by muse, mutect2, varscan2
- SLC45A2 | c.1368+3G>A | Splice Region (SNP) | VAF 12/282 reads (4%) | catalogued as rs757548370; called by muse, mutect2
- SLC4A10 | c.1163G>A p.G388D (on ENST00000446997 / NM_001354461.2; = p.G358D on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763287; called by muse, mutect2, varscan2
- SLC4A5 | c.2857del p.L953Cfs*16 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs1320472237; called by mutect2, pindel, varscan2
- SLC5A3 | c.1589G>C p.S530T | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62969086, COSV62973826; called by muse, mutect2, varscan2
- SLC6A3 | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs1176423145; called by muse, mutect2, varscan2
- SOX3 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100983692, COSV100983728, COSV65167994; called by muse, mutect2
- SOX3 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 45/576 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV100983657; called by muse, mutect2
- SPARCL1 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | catalogued as rs770742502; called by muse, mutect2
- SPEG | c.6942del p.R2315Gfs*38 | Frame Shift Del (DEL) | VAF 38/350 reads (11%) | catalogued as rs1452292712; called by mutect2, pindel
- SPON2 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377322914; called by muse, mutect2, varscan2
- SRRM2 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs143069128; called by muse, mutect2, varscan2
- STARD3 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748976068; called by muse, mutect2, varscan2
- STRA8 | c.179G>A p.R60H (on ENST00000275764; = p.R38H on NM_182489.2) | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs754296969; called by muse, mutect2, varscan2
- SULF1 | c.2393del p.L798Wfs*6 | Frame Shift Del (DEL) | VAF 16/129 reads (12%) | catalogued as COSV52694521; called by mutect2, pindel
- SV2A | c.374dup p.S127Efs*2 | Frame Shift Ins (INS) | VAF 20/115 reads (17%) | catalogued as rs1167154522; called by mutect2, varscan2
- SVEP1 | c.10466C>T p.S3489F | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs761351493; called by muse, mutect2, varscan2
- SYN3 | c.1155G>T p.M385I | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60513679; called by muse, mutect2, varscan2
- SZT2 | c.8626C>T p.R2876W (on ENST00000634258 / NM_001365999.1; = p.R2819W on NM_015284.4) | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.893); catalogued as rs747143141, COSV65171300; ClinVar: uncertain significance; called by muse, mutect2
- TACR1 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100537616; called by muse, mutect2, varscan2
- TADA3 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs759523634, COSV55028295; called by muse, mutect2, varscan2
- TAF1 | c.3446G>A p.R1149H (on ENST00000373790 / NM_138923.4; = p.R1170H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52119933; called by muse, mutect2, varscan2
- TASOR | c.541T>C p.Y181H | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1017358961; called by muse, mutect2, varscan2
- TCEAL8 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs772682413, COSV100749805; called by muse, mutect2, varscan2
- TCF25 | c.980C>T p.T327I | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1476064883; called by muse, mutect2, varscan2
- TCHH | c.825_827del p.E276del | In Frame Del (DEL) | VAF 31/219 reads (14%) | catalogued as rs758306380; called by pindel, varscan2
- TCTEX1D4 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1226753236; called by muse, mutect2, varscan2
- TDRD1 | c.203del p.L68Cfs*29 | Frame Shift Del (DEL) | VAF 17/142 reads (12%) | catalogued as rs1564933094, COSV52595869; called by mutect2, pindel, varscan2
- TENM1 | c.6055G>T p.G2019* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100948905; called by muse, mutect2, varscan2
- TEP1 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV99401828; called by muse, mutect2
- TERF2 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs777964323; called by muse, varscan2
- TEX10 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs1047446448, COSV66516765; called by muse, mutect2, varscan2
- TFR2 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 54/484 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs749498767, COSV56154302; called by muse, mutect2, varscan2
- TGFB3 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 58/369 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs1085307755, COSV99472675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIA1 | c.691C>T p.R231C (on ENST00000433529 / NM_001351511.1; = p.R220C on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs752346516, COSV57006097; called by muse, mutect2, varscan2
- TIGD4 | c.1219del p.A407Qfs*3 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as COSV58550799; called by mutect2, pindel, varscan2
- TJAP1 | c.1387C>T p.R463* (on ENST00000372445 / NM_001146016.1; = p.R453* on NM_080604.3) | Nonsense Mutation (SNP) | VAF 26/219 reads (12%) | catalogued as rs200207672; called by muse, mutect2, varscan2
- TJP3 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs756026835; called by muse, mutect2, varscan2
- TLN1 | c.6138G>T p.Q2046H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.407); catalogued as COSV59212792; called by muse, mutect2, varscan2
- TLR5 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 71/396 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as rs770192036; called by muse, mutect2, varscan2
- TM7SF3 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs779993448; called by muse, mutect2, varscan2
- TMA16 | c.45del p.V16Sfs*25 | Frame Shift Del (DEL) | VAF 15/117 reads (13%) | catalogued as rs570113265, COSV62187391; called by mutect2, varscan2
- TMCO6 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs749485111, COSV52798944; called by muse, mutect2, varscan2
- TMEM131 | c.3751G>A p.A1251T | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV51780451; called by muse, mutect2, varscan2
- TMEM221 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as rs978326775; called by muse, mutect2
- TMEM60 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs1562816897; called by muse, mutect2, varscan2
- TMEM63C | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs767883333; called by muse, mutect2, varscan2
- TMEM86A | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs746283594, COSV55011476; called by muse, mutect2
- TMX2 | c.391dup p.L131Pfs*6 | Frame Shift Ins (INS) | VAF 16/138 reads (12%) | catalogued as rs1274824614; called by mutect2, varscan2
- TNKS | c.3010G>A p.V1004I | Missense Mutation (SNP) | VAF 61/326 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs370349163; called by muse, mutect2, varscan2
- TNPO2 | c.2202G>A p.M734I | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100790448; called by muse, mutect2, varscan2
- TONSL | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs748017086; called by muse, varscan2
- TPST2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1346929845, COSV58681541; called by muse, mutect2, varscan2
- TRDN | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV62122458; called by muse, varscan2
- TRMT12 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1453677990; called by muse, mutect2, varscan2
- TSPOAP1 | c.5422G>A p.G1808S | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752560074; called by muse, mutect2, varscan2
- TSPYL1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs979950673, COSV100889623; called by muse, mutect2, varscan2
- TSSK1B | c.1075del p.Q359Nfs*43 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | catalogued as rs747842861, COSV101181233; called by mutect2, pindel, varscan2
- TTC22 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1231915762; called by muse, mutect2, varscan2
- TTC28 | c.6527C>T p.A2176V | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs764330777, COSV67416242; called by muse, mutect2
- TTC34 | c.1993G>A p.G665R | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.582); catalogued as rs761299025; called by muse, mutect2, varscan2
- TTC37 | c.1633-2A>G p.X545_splice | Splice Site (SNP) | VAF 31/159 reads (19%) | catalogued as rs371873101; called by muse, mutect2, varscan2
- TTN | c.19219G>A p.V6407I (on ENST00000591111; = p.V5480I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | PolyPhen possibly damaging (0.729); catalogued as rs140143513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TULP1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs62636707; ClinVar: not provided; called by muse, mutect2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as rs760251146; called by mutect2, varscan2
- UBE4B | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.267); catalogued as rs996720320, COSV53527181; called by muse, varscan2
- ULBP1 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as rs369005799; called by muse, mutect2, varscan2
- UNC13B | c.1199A>G p.Q400R | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.043); catalogued as rs1204534677, COSV65931887; called by muse, mutect2, varscan2
- USP1 | c.1985del p.N662Mfs*2 | Frame Shift Del (DEL) | VAF 52/218 reads (24%) | catalogued as rs751218576; ClinVar: not provided; called by mutect2, varscan2
- USP11 | c.1075G>A p.A359T (on ENST00000218348; = p.A316T on NM_001371072.1) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54472924; called by muse, mutect2, varscan2
- USP25 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 69/375 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53485662; called by muse, mutect2, varscan2
- USP35 | c.287del p.P96Rfs*94 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs1565394387; called by mutect2, pindel, varscan2
- VASH1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs145801473; called by muse, mutect2, varscan2
- VASH1 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.852); catalogued as rs549007706; called by muse, mutect2, varscan2
- VAT1L | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765788361; called by muse, mutect2, varscan2
- VPS13B | c.8297C>T p.T2766I | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs775503350; called by muse, mutect2, varscan2
- WASHC5 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs372031408; called by muse, mutect2, varscan2
- WNT10A | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM140733; called by muse, mutect2
- WNT9A | c.728T>C p.L243P | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55296255; called by muse, mutect2, varscan2
- XIRP1 | c.3402del p.W1135Gfs*2 | Frame Shift Del (DEL) | VAF 34/165 reads (21%) | catalogued as rs1166941994; called by mutect2, varscan2
- XIRP1 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202133354, COSV61137191; called by muse, mutect2, varscan2
- XIRP2 | c.1537dup p.D513Gfs*10 (on ENST00000628543; = p.D688Gfs*10 on NM_152381.6) | Frame Shift Ins (INS) | VAF 22/144 reads (15%) | catalogued as rs745648385; called by mutect2, varscan2
- YEATS2 | c.4058C>T p.A1353V | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.64); catalogued as rs1267738637, COSV100527582; called by muse, mutect2, varscan2
- ZBED1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1425481509, COSV58132830; called by muse, mutect2
- ZBTB38 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs191445074; called by muse, mutect2, varscan2
- ZBTB48 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1241247733; called by muse, mutect2
- ZFHX4 | c.8291C>T p.P2764L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.796); catalogued as rs755319742, COSV51468474; called by muse, mutect2, varscan2
- ZFP36L1 | c.164T>A p.V55D | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100322520; called by muse, mutect2, varscan2
- ZFPM2 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); catalogued as rs931953468; called by muse, mutect2, varscan2
- ZFPM2 | c.2781del p.N928Mfs*9 | Frame Shift Del (DEL) | VAF 56/284 reads (20%) | catalogued as COSV65872951; called by pindel, varscan2
- ZFR | c.1074del p.E359Kfs*4 | Frame Shift Del (DEL) | VAF 18/111 reads (16%) | catalogued as rs751974853; called by mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 26/216 reads (12%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF175 | c.191T>C p.F64S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1280016500; called by muse, mutect2, varscan2
- ZNF33B | c.2273_2275del p.F758del | In Frame Del (DEL) | VAF 19/118 reads (16%) | catalogued as rs1212318997; called by mutect2, pindel, varscan2
- ZNF524 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752853097; called by muse, mutect2, varscan2
- ZNF597 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.339); catalogued as COSV57084231; called by muse, mutect2, varscan2
- ZNF775 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1308018260; called by muse, mutect2
- ZNF793 | c.979A>G p.N327D | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as rs1171289689; called by muse, mutect2, varscan2
- ZNF83 | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs977603809; called by muse, mutect2
- ZNF862 | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs772423642, COSV56222819; called by muse, mutect2, varscan2
- ZSCAN22 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs762641497; called by muse, mutect2, varscan2
- ZSWIM4 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1175528817; called by muse, mutect2
- AARS1 | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 44/418 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- ABCC12 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ACTR5 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ACVR1C | c.1372G>T p.G458W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ADAM17 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 41/222 reads (18%) | called by muse, mutect2, varscan2
- ADGRL3 | c.1199A>T p.N400I (on ENST00000506720 / NM_001322402.2; = p.N332I on NM_015236.6) | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- AGRN | c.3709G>T p.V1237L | Missense Mutation (SNP) | VAF 54/284 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AHNAK | c.17038dup p.V5680Gfs*7 | Frame Shift Ins (INS) | VAF 46/264 reads (17%) | called by mutect2, pindel, varscan2
- AL645922.1 | c.1996T>C p.Y666H | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.151); called by muse, mutect2
- ALDH7A1 | c.1055A>C p.K352T | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.584); called by muse, mutect2
- ALMS1 | c.12014A>C p.N4005T | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- ANK1 | c.2141T>C p.I714T | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- ANKRD26 | c.4472_4474del p.A1491del | In Frame Del (DEL) | VAF 20/183 reads (11%) | called by mutect2, pindel, varscan2
- ANKRD28 | c.2048A>C p.D683A | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANKRD44 | c.2385dup p.C796Mfs*8 | Frame Shift Ins (INS) | VAF 18/144 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD50 | c.1771A>G p.T591A | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKUB1 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- APBB1IP | c.1987G>T p.G663C | Missense Mutation (SNP) | VAF 26/594 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2
- ARHGAP45 | c.1164G>A p.W388* | Nonsense Mutation (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- ARHGEF1 | c.1708del p.L570Cfs*44 | Frame Shift Del (DEL) | VAF 18/152 reads (12%) | called by pindel, varscan2
- ARHGEF40 | c.1574A>G p.D525G | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.1062dup p.Q355Tfs*45 | Frame Shift Ins (INS) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- ARMCX3 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- ASB15 | c.1080T>A p.N360K | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASCL4 | c.263G>A p.C88Y | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2
- ATG9A | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.09); called by muse, varscan2
- ATN1 | c.2249del p.P750Lfs*5 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ATP12A | c.2443del p.L815Cfs*33 | Frame Shift Del (DEL) | VAF 14/172 reads (8%) | called by mutect2, pindel
- ATP1A1 | c.1640dup p.L548Pfs*16 | Frame Shift Ins (INS) | VAF 10/84 reads (12%) | called by mutect2, pindel
- ATP2B2 | c.1073A>G p.D358G (on ENST00000352432; = p.D324G on NM_001683.5) | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.304); called by muse, mutect2
- ATP2B3 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AWAT1 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- BCKDK | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- BDH1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEST4 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- BICRAL | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 63/327 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BIN1 | c.1043C>G p.T348S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); called by muse, mutect2
- BIRC3 | c.1174A>G p.R392G | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2
- BRSK1 | c.2292del p.K765Rfs*88 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- BRWD3 | c.3434A>C p.E1145A | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.54); called by muse, mutect2
- BSN | c.10588C>T p.Q3530* | Nonsense Mutation (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- C11orf16 | c.1094T>C p.V365A | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2
- C11orf42 | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- C15orf39 | c.474C>A p.D158E | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- C17orf49 | c.127A>G p.T43A | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2
- C2orf73 | c.777G>C p.K259N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C3orf52 | c.15A>C p.Q5H | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.263); called by muse, mutect2
- C4orf17 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- C4orf54 | c.3587G>T p.R1196M | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- C5AR1 | c.263C>A p.A88E | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- C5orf34 | c.1073A>G p.D358G | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- C7orf33 | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 40/270 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CACNA1F | c.3674T>C p.L1225P | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNA1G | c.2096A>G p.D699G | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2
- CADPS | c.231del p.L78Cfs*20 | Frame Shift Del (DEL) | VAF 13/101 reads (13%) | called by mutect2, pindel, varscan2
- CAMSAP3 | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.854); called by muse, mutect2
- CASP6 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CATSPERD | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CBARP | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- CCDC120 | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CCDC6 | c.328_330del p.E110del | In Frame Del (DEL) | VAF 12/74 reads (16%) | called by pindel, varscan2
- CCSAP | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CD19 | c.1511T>C p.M504T (on ENST00000324662 / NM_001178098.2; = p.M503T on NM_001770.6) | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDC37 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2
- CDC42BPG | c.1210A>G p.S404G | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH18 | c.1923dup p.E642Rfs*18 | Frame Shift Ins (INS) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- CDK5R1 | c.758G>A p.C253Y | Missense Mutation (SNP) | VAF 100/522 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CECR2 | c.2581C>T p.R861* (on ENST00000342247 / NM_001290047.2; = p.R678* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- CECR2 | c.2833G>A p.V945I (on ENST00000342247 / NM_001290047.2; = p.V762I on NM_001290046.1) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); called by muse, mutect2
- CELF4 | c.1100-1G>A p.X367_splice | Splice Site (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- CEP290 | c.2651G>T p.R884M | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEP295NL | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CERT1 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CFAP161 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.037); called by muse, mutect2
- CFAP52 | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CHD7 | c.8159G>T p.R2720M | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- CHRNA5 | c.678C>A p.S226R | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- CHST8 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- CHUK | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CILP2 | c.3037A>G p.M1013V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIP2A | c.2146A>G p.K716E | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2
- CKAP4 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.23); called by muse, varscan2
- CLCN4 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, varscan2
- CLEC16A | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 41/194 reads (21%) | called by muse, mutect2, varscan2
- CLSTN3 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 37/410 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.396); called by muse, mutect2
- CLUH | c.2674del p.Q892Rfs*36 (on ENST00000435359; = p.Q931Rfs*36 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel
- CNDP2 | c.866dup p.D290Gfs*62 | Frame Shift Ins (INS) | VAF 14/121 reads (12%) | called by mutect2, pindel, varscan2
- CNGA1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.08); called by muse, mutect2
- CNNM2 | c.410del p.G137Afs*107 | Frame Shift Del (DEL) | VAF 24/258 reads (9%) | called by mutect2, pindel
- CNTLN | c.2320C>A p.L774M | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTLN | c.3668del p.K1223Rfs*8 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, varscan2
- COA1 | c.218T>G p.L73R | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- COL12A1 | c.4394C>A p.P1465H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL1A1 | c.805-2A>G p.X269_splice | Splice Site (SNP) | VAF 39/409 reads (10%) | called by muse, mutect2, varscan2
- COL22A1 | c.2196T>G p.G732= | Splice Region (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- COL24A1 | c.4162C>T p.Q1388* | Nonsense Mutation (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- COL25A1 | c.1764+1del p.X588_splice | Splice Site (DEL) | VAF 23/165 reads (14%) | called by mutect2, pindel, varscan2
- COL4A5 | c.2820del p.G941Vfs*55 | Frame Shift Del (DEL) | VAF 20/175 reads (11%) | called by mutect2, pindel, varscan2
- COL6A5 | c.2813C>T p.A938V | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- COL7A1 | c.7069-2A>G p.X2357_splice | Splice Site (SNP) | VAF 40/414 reads (10%) | called by muse, mutect2
- COPS2 | c.1012A>G p.M338V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- COX6B1 | c.-11-6C>A | Splice Region (SNP) | VAF 44/410 reads (11%) | called by muse, mutect2
- CPEB1 | c.1182del p.F394Lfs*4 (on ENST00000617958; = p.F334Lfs*4 on NM_030594.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/171 reads (8%) | called by mutect2, pindel
- CRB1 | c.490del p.Q164Rfs*42 | Frame Shift Del (DEL) | VAF 20/153 reads (13%) | called by mutect2, pindel, varscan2
- CSDE1 | c.1315del p.S439Pfs*28 (on ENST00000358528 / NM_001007553.3; = p.S408Pfs*28 on NM_007158.6) | Frame Shift Del (DEL) | VAF 14/144 reads (10%) | called by mutect2, pindel
- CSF3 | c.97del p.L33Wfs*16 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- CSNK1E | c.989del p.P330Lfs*47 | Frame Shift Del (DEL) | VAF 9/113 reads (8%) | called by mutect2, pindel
- CSPP1 | c.2373G>T p.E791D (on ENST00000676605; = p.E750D on NM_024790.6) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTCF | c.2070dup p.E691Rfs*5 | Frame Shift Ins (INS) | VAF 24/84 reads (29%) | called by mutect2, varscan2
- CTNND1 | c.1346del p.N449Tfs*49 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | called by mutect2, pindel, varscan2
- CUL4B | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2
- CYRIA | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCHS1 | c.4643C>T p.S1548L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- DDHD1 | c.85C>T p.R29W (on ENST00000323669; = p.R260W on NM_030637.3) | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DDX11 | c.2306C>T p.A769V (on ENST00000545668 / NM_152438.2; = p.A719V on NM_004399.3) | Missense Mutation (SNP) | VAF 40/407 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DENND2B | c.986del p.G329Afs*4 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- DGKQ | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- DIMT1 | c.239del p.K80Rfs*11 | Frame Shift Del (DEL) | VAF 25/138 reads (18%) | called by mutect2, pindel, varscan2
- DIP2B | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 24/367 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2
- DIP2B | c.3692A>G p.N1231S | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0.001); called by muse, mutect2
- DIP2C | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2
- DIPK1B | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DMRTB1 | c.890del p.P297Rfs*13 | Frame Shift Del (DEL) | VAF 31/176 reads (18%) | called by pindel, varscan2
- DNAH12 | c.5694A>C p.K1898N (on ENST00000351747; = p.K1917N on NM_001366028.2) | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH12 | c.754A>T p.T252S | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH3 | c.3890A>C p.E1297A | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DNAJC22 | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNHD1 | c.5710G>T p.A1904S | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.162); called by muse, mutect2
- DOCK5 | c.3522del p.K1174Nfs*4 | Frame Shift Del (DEL) | VAF 9/90 reads (10%) | called by mutect2, pindel
- DOP1A | c.5224T>C p.Y1742H | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DPP4 | c.1176del p.D393Tfs*15 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- DVL2 | c.2093C>A p.P698H | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DYSF | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 96/445 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- DYSF | c.5729T>C p.I1910T | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- ECHDC1 | c.267del p.V90* (on ENST00000531967 / NM_001139510.1; = p.V84* on NM_018479.3) | Frame Shift Del (DEL) | VAF 8/95 reads (8%) | called by mutect2, pindel
- EEF1D | c.688dup p.A230Gfs*38 | Frame Shift Ins (INS) | VAF 25/174 reads (14%) | called by mutect2, pindel, varscan2
- EFCAB7 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EFHC1 | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 30/355 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.041); called by muse, mutect2
- EFNA4 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); called by muse, mutect2
- EIF5A | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 74/425 reads (17%) | called by muse, mutect2, varscan2
- ELP2 | c.1964T>C p.F655S | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2
- ENAM | c.1909C>T p.L637F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ENDOG | c.376C>A p.R126S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ENPEP | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2
- EPHA5 | c.1074del p.S359Lfs*63 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | called by mutect2, pindel, varscan2
- EPN3 | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2
- ETV3 | c.1507del p.Q503Rfs*31 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | called by mutect2, pindel, varscan2
- EVC | c.2237A>G p.Q746R | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EVC2 | c.2856_2857del p.R952Sfs*51 | Frame Shift Del (DEL) | VAF 69/430 reads (16%) | called by pindel, varscan2
- EXOSC4 | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 33/363 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- F5 | c.5856del p.K1952Nfs*21 | Frame Shift Del (DEL) | VAF 31/298 reads (10%) | called by mutect2, pindel
- FAM133B | c.271dup p.R91Kfs*13 | Frame Shift Ins (INS) | VAF 24/126 reads (19%) | called by mutect2, varscan2
- FAM171A2 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- FAM200A | c.1495del p.W499Gfs*11 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- FANCA | c.358A>G p.S120G | Missense Mutation (SNP) | VAF 83/505 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCM | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- FBLN1 | c.859C>A p.R287S | Missense Mutation (SNP) | VAF 69/349 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO40 | c.*3del | Frame Shift Del (DEL) | VAF 22/150 reads (15%) | called by mutect2, pindel
- FER1L5 | c.5979_5981delinsG p.Y1994Sfs*19 (on ENST00000623019; = p.Y1958Sfs*19 on NM_001293083.2) | Frame Shift Del (DEL) | VAF 30/147 reads (20%) | called by pindel, varscan2*
- FIZ1 | c.590dup p.L197Ffs*187 | Frame Shift Ins (INS) | VAF 10/64 reads (16%) | called by mutect2, pindel, varscan2
- FLG | c.12170A>G p.Y4057C | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- FMN1 | c.3835G>T p.A1279S (on ENST00000616417 / NM_001277313.2; = p.A1056S on NM_001103184.4) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.632); called by muse, mutect2
- FMN2 | c.3952del p.I1318Lfs*6 | Frame Shift Del (DEL) | VAF 13/106 reads (12%) | called by mutect2, pindel, varscan2
- FMO1 | c.117dup p.L40Afs*9 | Frame Shift Ins (INS) | VAF 37/158 reads (23%) | called by mutect2, pindel, varscan2
- FN1 | c.3797-1G>A p.X1266_splice | Splice Site (SNP) | VAF 34/242 reads (14%) | called by muse, mutect2, varscan2
- FNTA | c.1040A>G p.E347G | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- FOXI1 | c.78del p.E27Rfs*2 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- FRMD4A | c.296T>A p.V99D | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSIP1 | c.1301T>C p.I434T | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.19870A>G p.I6624V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); called by muse, mutect2
- FZR1 | c.1124del p.G375Afs*14 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | called by pindel, varscan2
- GABRB2 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); called by muse, mutect2
- GAGE2A | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 71/1760 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.301); called by muse, mutect2
- GANAB | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.838); called by muse, mutect2
- GAPVD1 | c.3156C>A p.N1052K (on ENST00000394104; = p.N1079K on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.018); called by muse, mutect2
- GDF10 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- GIGYF1 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- GIPC1 | c.580G>A p.V194M | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GLB1L | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLB1L3 | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- GLI3 | c.457A>C p.I153L | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GNAI1 | c.145A>C p.I49L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); called by muse, mutect2
- GPR39 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.78); called by muse, mutect2
- GPRIN2 | c.437T>G p.L146R | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIN3A | c.767T>G p.I256S | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- GRIP2 | c.1696C>T p.L566F (on ENST00000619221; = p.L469F on NM_001080423.4) | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GRM3 | c.579dup p.D194Rfs*10 | Frame Shift Ins (INS) | VAF 45/234 reads (19%) | called by mutect2, varscan2
- GUCD1 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.722); called by muse, mutect2
- HDLBP | c.3788C>A p.P1263H | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- HEATR9 | c.1091A>G p.Q364R | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- HELZ | c.5669del p.G1890Afs*37 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- HIPK1 | c.360del p.K120Nfs*4 | Frame Shift Del (DEL) | VAF 87/491 reads (18%) | called by mutect2, pindel, varscan2
- HIPK3 | c.2942C>T p.S981F | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HMCN1 | c.7312G>T p.G2438* | Nonsense Mutation (SNP) | VAF 23/161 reads (14%) | called by muse, mutect2, varscan2
- HMCN2 | c.9058A>G p.N3020D | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- HMGCR | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNMT | c.197T>A p.I66N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HOXB8 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2
- HOXD12 | c.363del p.E122Sfs*51 | Frame Shift Del (DEL) | VAF 24/260 reads (9%) | called by mutect2, pindel
- HPS6 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 68/487 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- HPS6 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 81/425 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by muse, varscan2
- HSP90B1 | c.2043G>T p.Q681H | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HSPA12B | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HSPA12B | c.1916G>A p.C639Y | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HSPA4L | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPG2 | c.13037del p.G4346Afs*70 | Frame Shift Del (DEL) | VAF 32/260 reads (12%) | called by mutect2, pindel, varscan2
- HSPG2 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- HSPH1 | c.1542G>T p.M514I | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUWE1 | c.8898A>T p.E2966D | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IGKV1-12 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 54/896 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2
- IGSF5 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); called by muse, mutect2
- ILRUN | c.540G>T p.E180D (on ENST00000374023 / NM_024294.4; = p.E114D on NM_022758.6) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.189); called by muse, varscan2
- INO80 | c.685del p.R229Dfs*45 | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | called by mutect2, pindel
- INPPL1 | c.3442G>T p.G1148C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- INSL6 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 17/179 reads (9%) | called by muse, mutect2
- IQCD | c.1330A>G p.K444E (on ENST00000416617 / NM_001330452.2; = p.K342E on NM_138451.3) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.243); called by muse, varscan2
- IRF6 | c.695A>C p.Y232S | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IRGM | c.434G>A p.W145* | Nonsense Mutation (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- IST1 | c.253C>A p.L85M (on ENST00000535424 / NM_001270976.1; = p.L72M on NM_014761.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); called by muse, mutect2
- ITGB8 | c.1827_1828dup p.G610Vfs*75 | Frame Shift Ins (INS) | VAF 48/378 reads (13%) | called by mutect2, varscan2
- ITPR2 | c.7064T>G p.V2355G | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- ITPRID1 | c.914A>G p.K305R | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- JPH1 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 32/413 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JPH3 | c.1262del p.P421Lfs*50 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- KALRN | c.8155del p.M2719* (on ENST00000360013 / NM_001024660.4; = p.M1022* on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/254 reads (11%) | called by mutect2, pindel
- KBTBD2 | c.1315A>G p.M439V | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCNAB2 | c.791G>T p.R264I | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- KCNC1 | c.970C>A p.L324M | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH8 | c.2158del p.E720Rfs*32 | Frame Shift Del (DEL) | VAF 33/201 reads (16%) | called by mutect2, pindel, varscan2
- KCNK1 | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA0895L | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- KIAA1109 | c.1829del p.N610Ifs*7 | Frame Shift Del (DEL) | VAF 24/210 reads (11%) | called by mutect2, pindel
- KIF4B | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KIT | c.129del p.K43Nfs*4 | Frame Shift Del (DEL) | VAF 29/196 reads (15%) | called by mutect2, pindel, varscan2
- KLF4 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KLHL9 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- KMT2B | c.6368del p.G2123Vfs*30 | Frame Shift Del (DEL) | VAF 22/162 reads (14%) | called by mutect2, pindel, varscan2
- KMT2C | c.10895dup p.P3633Tfs*19 | Frame Shift Ins (INS) | VAF 33/204 reads (16%) | called by mutect2, pindel, varscan2
- KMT2C | c.4868A>G p.E1623G | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KMT2D | c.15515G>A p.G5172E | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRT27 | c.1166G>A p.C389Y | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- KRT36 | c.410G>A p.C137Y | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2
- KRTAP11-1 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 11/319 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- KRTAP5-5 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 35/173 reads (20%) | PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KY | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.43); called by muse, mutect2
- LAMA5 | c.11063_11072del p.G3688Afs*36 | Frame Shift Del (DEL) | VAF 14/148 reads (9%) | called by mutect2, pindel
- LAMA5 | c.2750T>C p.V917A | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- LAMP3 | c.150del p.K50Nfs*15 | Frame Shift Del (DEL) | VAF 20/199 reads (10%) | called by mutect2, pindel
- LARGE1 | c.1747C>T p.L583F | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- LARGE1 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LDB3 | c.1937G>A p.S646N | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- LENG9 | c.1118del p.P373Lfs*3 | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | called by mutect2, pindel, varscan2
- LPIN2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- LRRC37A2 | c.3706T>C p.S1236P | Missense Mutation (SNP) | VAF 64/1070 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2
- LRRIQ1 | c.2525T>G p.L842R | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRK1 | c.1379del p.N460Tfs*19 | Frame Shift Del (DEL) | VAF 17/130 reads (13%) | called by mutect2, pindel, varscan2
- LRRN1 | c.739del p.Y247Mfs*19 | Frame Shift Del (DEL) | VAF 11/130 reads (8%) | called by mutect2, pindel
- LRRN3 | c.1901G>T p.G634V | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- LSAMP | c.209T>G p.I70S | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTBP2 | c.5446del p.H1816Tfs*32 | Frame Shift Del (DEL) | VAF 60/250 reads (24%) | called by mutect2, varscan2
- LTBP3 | c.1784del p.P595Lfs*23 | Frame Shift Del (DEL) | VAF 37/443 reads (8%) | called by mutect2, pindel
- MAGI1 | c.1362G>T p.Q454H | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- MAMSTR | c.1169del p.P390Hfs*30 (on ENST00000318083 / NM_001130915.2; = p.P287Hfs*30 on NM_182574.2) | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel, varscan2
- MAN2B1 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- MAP2K5 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAP3K9 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MAP4 | c.2994del p.V999* | Frame Shift Del (DEL) | VAF 19/160 reads (12%) | called by mutect2, pindel, varscan2
- MARCHF1 | c.415C>A p.L139I (on ENST00000274056; = p.L122I on NM_017923.4) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MATR3 | c.2078del p.K693Rfs*8 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- MBD3L3 | c.436T>G p.F146V | Missense Mutation (SNP) | VAF 39/903 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.056); called by muse, mutect2
- MCF2L | c.803G>A p.S268N (on ENST00000375608; = p.S236N on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- MCIDAS | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MCM10 | c.2289del p.E764Nfs*7 (on ENST00000484800 / NM_182751.3; = p.E763Nfs*7 on NM_018518.5) | Frame Shift Del (DEL) | VAF 16/216 reads (7%) | called by mutect2, pindel
- MCM7 | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 94/491 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEAF6 | c.382T>G p.F128V | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MECOM | c.2642C>T p.T881I (on ENST00000468789 / NM_001105078.4; = p.T1069I on NM_004991.4) | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MED15 | c.1859C>A p.P620Q (on ENST00000263205 / NM_001003891.3; = p.P580Q on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED23 | c.3998C>T p.T1333I | Missense Mutation (SNP) | VAF 27/310 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- MEGF8 | c.1641del p.F548Lfs*163 (on ENST00000251268 / NM_001271938.2; = p.F548Lfs*189 on NM_001410.3) | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- MELK | c.1861C>A p.P621T | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.159); called by muse, mutect2
- METTL16 | c.564del p.F188Lfs*10 | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | called by mutect2, pindel
- MGA | c.5782G>T p.G1928* (on ENST00000219905 / NM_001164273.1; = p.G1719* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 23/139 reads (17%) | called by muse, mutect2, varscan2
- MGAM2 | c.2796del p.C933Vfs*30 | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel
- MGRN1 | c.1318A>G p.S440G | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIA3 | c.841T>G p.S281A | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MIDN | c.561del p.V188Cfs*86 | Frame Shift Del (DEL) | VAF 25/140 reads (18%) | called by mutect2, pindel, varscan2
- MIER3 | c.769T>C p.C257R | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MISP | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.181); called by muse, mutect2
- MKS1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 72/416 reads (17%) | called by muse, mutect2, varscan2
- MOAP1 | c.256G>T p.G86W | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRGPRF | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, mutect2
- MRPS2 | c.227A>C p.K76T | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); called by muse, mutect2
- MRPS26 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.237); called by muse, mutect2
- MTMR4 | c.403T>C p.W135R | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MTOR | c.2804T>C p.L935P | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- MTTP | c.2654A>G p.Q885R | Missense Mutation (SNP) | VAF 32/343 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2
- MUC16 | c.28306C>A p.L9436M | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MUC20 | c.1868G>T p.S623I | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- MUC5B | c.319T>C p.C107R | Missense Mutation (SNP) | VAF 31/424 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH1 | c.2734C>G p.L912V | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- MYH7 | c.5225A>G p.E1742G | Missense Mutation (SNP) | VAF 71/428 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- MYLIP | c.95G>T p.R32M | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, varscan2
- MYO15A | c.3467G>A p.C1156Y | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYOM1 | c.2671C>A p.L891M | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- MYPN | c.2671del p.I891* | Frame Shift Del (DEL) | VAF 68/400 reads (17%) | called by mutect2, varscan2
- NARS1 | c.545A>C p.Y182S | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- NAT8 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); called by muse, mutect2
- NAV3 | c.6058dup p.X2020_splice (on ENST00000397909 / NM_001024383.2; = p.X1998_splice on NM_014903.6) | Splice Site (INS) | VAF 8/83 reads (10%) | called by mutect2, pindel
- NCAPG2 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCAPH | c.1258del p.L420Ffs*4 | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | called by mutect2, pindel, varscan2
- NCOR1 | c.4833_4836del p.T1612Sfs*2 | Frame Shift Del (DEL) | VAF 40/263 reads (15%) | called by pindel, varscan2
- NDST1 | c.1310A>G p.Y437C | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- NDST1 | c.2536G>T p.A846S | Missense Mutation (SNP) | VAF 46/433 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEDD4L | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2
- NEDD4L | c.950T>A p.I317N | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- NEO1 | c.2169G>T p.W723C | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- NES | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NHSL1 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- NIPSNAP3A | c.430G>T p.G144* | Nonsense Mutation (SNP) | VAF 32/212 reads (15%) | called by muse, mutect2, varscan2
- NISCH | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NKX6-2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NLRC5 | c.508dup p.H170Pfs*37 | Frame Shift Ins (INS) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- NLRP5 | c.1918C>A p.L640I | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NOBOX | c.1390del p.Q464Nfs*2 | Frame Shift Del (DEL) | VAF 19/99 reads (19%) | called by mutect2, pindel, varscan2
- NOS1 | c.3593C>A p.A1198D | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NOVA1 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- NPFFR1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPY5R | c.1124T>C p.L375S | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- NR2F1 | c.192del p.G65Afs*54 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | called by mutect2, pindel
- NRBP1 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); called by muse, mutect2
- NRBP2 | c.1437G>T p.E479D | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NRK | c.1463C>A p.P488H | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- NSD1 | c.5397dup p.G1800Wfs*3 | Frame Shift Ins (INS) | VAF 58/335 reads (17%) | called by mutect2, pindel, varscan2
- NSD3 | c.1255dup p.T419Nfs*28 | Frame Shift Ins (INS) | VAF 50/296 reads (17%) | called by mutect2, varscan2
- NUP188 | c.4553T>A p.V1518D | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.019); called by muse, mutect2
- NUP35 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.501); called by muse, mutect2
- NUS1 | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- ODC1 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 78/456 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.036); called by muse, mutect2, varscan2
716 further variants in this file (246 protein-altering or splice-affecting, 288 silent, 182 other) are not listed here.
